Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A215, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A215-01A (Primary Tumor).

[page 1 of 6]
1CD-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1 /w 4/8/11

SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

A: Uterus and cervix, left fallopian tube and ovary,
hysterectomy with left
salpingo-oophorectomy:

Location of tumor: Endometrium, anterior and posterior corpus,
fundus, and
lower uterine segments

Histologic type: Endometrioid adenocarcinoma with focal squamous
differentiation

Histologic grade (FIGO): FIGO 3 ✓

Extent of invasion: Invasion present

Myometrial invasion: Inner half

Depth: 4 mm Wall thickness: 1.2 cm Percent: 33% (A6) (see
comment)

Serosal involvement: Not identified

Lower uterine segment involvement: present, involving
endometrium of the
anterior LUS, and myometrial invasion of the posterior LUS (1 mm
invasion of the
posterior LUS (wall thickness 1.2 cm))

Cervical involvement: Not identified

Adnexal involvement (see below): Not identified

Other sites: N/A

Cervical/vaginal margin and distance: Widely free

Lymphovascular Space Invasion: Present (A6, A9, A10)

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 21

Other Pathologic findings:

Pathologist Initials	QUAIFIED	DISQUALIFIED

4/8/11

[page 2 of 6]
- Cervix: Nabothian cyst, chronic cervicitis

Tumor estrogen receptor and progesterone receptor immunohistochemistry results:

ER positive (2-3+, 90%) and PR receptor positive (2-3+, 75%) (A6)

AJCC Pathologic stage: pT1a pN 0 pMx

FIGO (2008 classification) Stage grouping: 1A

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review

Ovary, left, oophorectomy:

- Atrophic ovary with surface inclusion glands
- No malignancy identified

Fallopian tube, left, salpingectomy:

- Hydrosalpinx
- Tubal ligation by gross examination
- Peritubal cysts
- No malignancy identified.

B: Lymph nodes, right pelvic, removal

- Five lymph nodes with no metastatic carcinoma identified (0/5)
- All tissue submitted for microscopic examination.

C: Lymph nodes, left pelvic, removal

- Two lymph nodes with no metastatic carcinoma identified (0/2)
- All tissue submitted for microscopic examination.

D: Lymph node, right periaortic, removal

- Eleven lymph nodes with no metastatic carcinoma identified (0/11)
- All tissue submitted for microscopic examination.

E: Lymph node, left periaortic, removal

- Three lymph nodes with no metastatic carcinoma identified (0/3)
- All tissue submitted for microscopic examination.

Comment:

[page 3 of 6]
Amendment Comment:

After presentation at (

clinical request was made to review depth of invasion to further clarify inner half (<50%) versus outer half (>50%) invasion, given that original measurement was exactly at 50%. Per intradepartmental review, the consensus is invasion into the inner half (33%) (A6). Drs. agree (intradepartmental consultation). Immunohistochemical stain for CD31 was performed on block A6 and highlights a vessel around the focus initially measured at 50% invasion, demonstrating that this deeper focus is lymphovascular invasion and not deep myometrial invasion. Therefore, the stage is amended to pT1a from pT1b. The other diagnoses are unchanged. A telephone message was sent to Dr. regarding this amendment on

Clinical History:

The patient is a -year-old female with endometrial adenocarcinoma.

Gross Description:

Received are five appropriately labeled containers.

Specimen A is additionally labeled "uterus, cervix LSO".

Adnexa: Present on left side only

Weight: 99.2 grams

Shape: Pear shaped

Dimensions:

height: 9.0 cm

anterior to posterior width: 4.0 cm

breadth at fundus: 6.0 cm

Serosa: Pink/tan and hyperemic

Cervix:

length of endocervical canal: 2.0 cm

ectocervix: Pink/tan and smooth

endocervix: Tan and trabeculated

Endomyometrium:

length of endometrial cavity: 4.2 cm

width of endometrial cavity at fundus: 3.8 cm

[page 4 of 6]
tumor findings:

dimensions: 8.7 x 3.8 x 0.5 cm

appearance: Tumor is a white/tan, shaggy, soft mass with an exophytic growth pattern

location and extent: Mass extends from the lower uterine segment of the anterior across the corpus and fundus to the lower uterine

segment of the posterior.

myometrial invasion: No apparent invasion.

thickness of myometrial wall at deepest gross invasion: 1.2 cm

other findings or comments: None

Adnexa:

Left ovary:

dimensions: 2.5 x 1.1 x 0.7 cm

external surface: Yellow/tan and vaguely lobulated

cut surface: Yellow/white and whorled

Left fallopian tube:

dimensions: 5.5 x 0.7 cm

other findings: Tubes have been ligated in the past;

peritubal cysts

Lymph nodes: Received separately

Other comments: No

Digital photograph taken: No

Tissue submitted for special investigations: Tumor only to tissue

procurement

Block Summary:

A1 - anterior cervix

A2 - anterior lower uterine segment

A3 - anterior left corpus

A4 - anterior right corpus

A5 - anterior fundus, left

A6 - anterior fundus, right

A7 - posterior cervix

A8 - posterior lower uterine segment

A9 - posterior corpus, left

A10 - posterior corpus, right

A11 - posterior fundus, left

A12 - posterior fundus, right

A13 - left ovary and left fallopian tube

[page 5 of 6]
Specimen B is additionally labeled "right pelvic node" and is received in formalin. The specimen consists of two fragments of yellow/tan fibroadipose tissue with an aggregate measurement of 4.5 x 3 x 1.5 cm. Dense fibroadipose tissue. Three lymph node candidates are identified and range in size from 1.0 up to 2.5 cm in greatest dimension.

Block Summary:

B1 - One lymph node candidate
B2 - One lymph node candidate
B3-B4 - Largest lymph node candidate, sectioned,

Specimen C is additionally labeled "left pelvic node" and is received in formalin. The specimen consists of multiple fragments of yellow/tan fibroadipose tissue with an aggregate measurement of 4.5 x 2.5 x 1.5 cm. Dense fibroadipose tissue. Two lymph node candidates are identified and range in size from 1.0 up to 2.0 cm in greatest dimension.

Block Summary:

C1 - One lymph node candidate
C2 - One lymph node candidate
C3 - Remaining fibroadipose tissue,

Specimen D is additionally labeled "right periaortic node" and is received in formalin. The specimen consists of a single fragment of fibroadipose tissue that measures 3.5 x 2.0 x 1.2 cm. Within fibroadipose tissue one lymph node candidate is identified and measures 2 cm.

Block Summary:

D1 - One lymph node candidate
D2 - Remaining fibroadipose tissue,

Specimen E is additionally labeled "left periaortic node" and is received in formalin. The specimen consists of a single fragment of yellow/tan fibroadipose tissue that measures 3.2 x 1.5 x 1.0 cm. Within fibroadipose

[page 6 of 6]
tissue one lymph
node candidate is identified and measures approximately 2 cm in
greatest
dimension.

Block Summary:
E1-E2 - One lymph node candidate,

Grossing Pathologist:

Light Microscopy:
Light microscopic examination performed by Dr.

Signature
Resident Physician:
Attending Pathologist:, M.D., Ph.D.

I have personally conducted the evaluation of the above
specimens and have
rendered the above diagnosis(es).

Electronically Signed by:, M.D., Ph.D.
Date

Source: NCI Genomic Data Commons file c89631e0-c870-4151-a184-8f16bd0887e1 (TCGA-EY-A215.C0F970E3-E534-4A34-B87A-4383FD261B53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).